Somatic mutation profile of tumor specimen TCGA-TT-A6YK-01A (aliquot TCGA-TT-A6YK-01A-11D-A35I-08) from TCGA case TCGA-TT-A6YK, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Extra-adrenal paraganglioma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of abdomen; Age at diagnosis: 61.6 years (22,500 days).
Specimen TCGA-TT-A6YK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) df9605ea-9529-4af0-98e0-88e25d4a84f9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-TT-A6YK-10A (Blood Derived Normal), aliquot TCGA-TT-A6YK-10A-01D-A35G-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5b58ff2b-3b49-4e0b-8a2f-88c4fe67ac23

The open-access MAF lists 11 somatic variants for this specimen: 8 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 7, Silent 3, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PMM1 | c.432C>G p.S144R | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.45); catalogued as rs771466946; called by muse, mutect2, varscan2
- XPO7 | c.259C>A p.R87= | Splice Region (SNP) | VAF 3/12 reads (25%) | catalogued as COSV53010859, COSV99382155; called by muse, mutect2
- GFI1B | c.826C>A p.H276N | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- IGSF9B | c.1709A>T p.D570V | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT tolerated (0.07); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- PCNX1 | c.6026T>G p.L2009R | Missense Mutation (SNP) | VAF 4/64 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- PLEKHA7 | c.805G>T p.D269Y | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- PMM1 | c.433T>A p.C145S | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.537); called by muse, mutect2, varscan2
- TEX11 | c.2044A>G p.T682A (on ENST00000344304; = p.T667A on NM_031276.3) | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- DIDO1 | c.309C>G p.P103= | Silent (SNP) | VAF 16/42 reads (38%) | catalogued as COSV99824365; called by muse, varscan2
- NFATC1 | c.165C>T p.A55= | Silent (SNP) | VAF 7/106 reads (7%) | called by muse, mutect2
- SETDB2 | c.1110G>A p.Q370= | Silent (SNP) | VAF 13/115 reads (11%) | catalogued as COSV99320568; called by muse, mutect2, varscan2
